Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GW, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GW-01A (Primary Tumor).

11/30/11

Pathology

Pathology,
Fax:

DOB:
Physician:
Accession:

Sex: F

Collected:

Received:

Case type: Surgical Case

1CD-0-3

Path: carcinoma, papillary and follicular 8340/3
Site: thyroid, NOS C73.9 11/30/11

DIAGNOSIS

(A) DELPHIAN TISSUE:

Fibroadipose tissue, negative for tumor.

CQCF: carcinoma, papillary, thyroid 8260/3

(B) TOTAL THYROID:

PAPILLARY THYROID CARCINOMA, CONVENTIONAL AND FOLLICULAR PATTERNS

Location: Right lobe

Multi-focal: No

Size = 2.5 cm

Extrathyroidal extension: Absent

Lymphovascular invasion: Absent

Resection Margins: Negative

GROSS DESCRIPTION

(A) DELPHIAN TISSUE – One pale-gray tissue fragment (0.6 x 0.3 x 0.3 cm). Entirely submitted in A.

(B) TOTAL THYROID – A total thyroidectomy with slightly symmetric lobes with the right lobe (5.0 x 3.0 x 2.0 cm) and left lobe (3.5 x 1.5 x 1.0 cm). Within the inferior/posterior aspect of the right lobe is a variegated soft multinodular nodule (2.5 x 1.7 x 1.5 cm) which is confined with a thin rim of tissue to the thyroid. The nodule shows varying thickness of peripheral fibrosis and hemorrhage. The remainder of the thyroid is unremarkable.

SECTION CODE: B1, B2, left lobe superior-to-inferior; B3, isthmus; B4, unremarkable superior right lobe; B5-B8, right lobe with nodule.

CLINICAL HISTORY

Papillary thyroid cancer

SNOMED CODES

T-B6000, M-80503,

"Some tests reported here may have been developed and performance characteristics determined by These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

Source: NCI Genomic Data Commons file 471d5862-81cf-4080-b632-be04773d3694 (TCGA-EL-A3GW.9093C3DC-F933-4705-86BF-9CA24A98C624.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).